Gene-level copy-number profile of tumor specimen TCGA-DX-A3LY-01B from TCGA case TCGA-DX-A3LY, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 66.2 years (24,166 days).
Specimen TCGA-DX-A3LY-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.415a058a-072a-4088-baa5-7387efd002ed.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A3LY-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4d70ee95-02f4-4528-8938-7310e61ff381

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 1,177; copy number 2: 4,287; copy number 3: 14,960; copy number 4: 32,352; copy number 5: 4,049; copy number 6: 1,237; copy number 7: 395; copy number 8: 390; copy number 9: 98; copy number 10: 54; copy number 11: 52; copy number 12: 24; copy number 13: 54; copy number 14: 1; copy number 15: 10; copy number 16: 6; copy number 17: 19; copy number 18: 78; copy number 19: 45; copy number 20: 46; copy number 21: 13; copy number 22: 154; copy number 23: 9; copy number 24: 121; copy number 27: 19; copy number 28: 2; copy number 31: 1; copy number 32: 4; copy number 33: 73; copy number 38: 58; copy number 40: 16; copy number 44: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A3LY-01B-11D-A27O-01): tumor purity 0.59, ploidy 3.83, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 731 genes in 51 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:207,645,113–207,738,416, 1 gene, copy number 10 (within-gene range 4–10): CR1L.
- chr1:207,708,898–208,736,286, 18 genes, copy number 10: RNA5SP534, AL137789.2, CD46, CDCA4P4, MIR29B2CHG, MIR29C, MIR29B2, CD34, AL356275.1, LINC02767, PLXNA2, AL590138.1, AL606753.1, AL606753.2, LINC01735, LINC02769, RPS26P13, LINC01717.
- chr1:220,528,136–220,664,461, 1 gene, copy number 19 (within-gene range 4–19): MARK1.
- chr1:220,625,740–221,563,653, 17 genes, copy number 19: HDAC1P2, C1orf115, MTARC2, MTARC1, AL445423.3, RNU6ATAC35P, AL445423.2, AL445423.1, LINC01352, HLX-AS1, HLX, AL445466.1, LINC02817, AL360013.2, AL360013.3, AL360013.1, AL360013.4.
- chr1:238,107,736–238,108,567, 1 gene, copy number 11: YWHAQP9.
- chr3:138,652,698–139,782,699, 25 genes, copy number 11 (within-gene range 4–11): PIK3CB, GAPDHP39, RPL23AP40, EEF1A1P25, ATP5MC1P3, LINC01391, FOXL2, FOXL2NB, PRR23A, MRPS22, PRR23B, PRR23C, RPL7L1P7, BPESC1, PISRT1, AC119740.1, AC024933.2, AC024933.1, COPB2, U6, AC046134.2, RBP2, AC097103.1, ACTG1P1, RBP1.
- chr3:139,582,928–139,609,939, 3 genes, copy number 11: AC046134.1, RN7SKP124, RN7SL724P.
- chr3:142,815,922–144,445,844, 23 genes, copy number 10: PCOLCE2, AC021074.1, AC021074.3, PAQR9, AC021074.2, PAQR9-AS1, U2SURP, AC026304.1, AC018450.2, CHST2, AC018450.1, PBX2P1, SLC9A9, AC131210.1, SLC9A9-AS1, SLC9A9-AS2, GAPDHP47, ST13P15, AC073358.1, AC107421.1, DIPK2A, RNA5SP144, AC011592.1.
- chr3:146,996,607–148,401,084, 16 genes, copy number 11: RNU6-505P, RPL21P71, ZIC4, ZIC4-AS1, ZIC1, NPM1P28, AC092925.1, AC092958.1, AC092958.4, LINC02032, AC092958.3, AC092958.2, AC025566.1, HNRNPA1P20, LINC02045, LINC02046.
- chr3:155,657,760–156,817,062, 24 genes, copy number 12 (within-gene range 8–12): RPL6P7, AC104472.1, AC104472.2, C3orf33, AC104472.3, SLC33A1, AC104472.4, GMPS, AC104472.5, SETP14, VN2R1P, KCNAB1, ALG1L15P, MRE11P1, AC091607.2, AC091607.1, KCNAB1-AS2, KCNAB1-AS1, AC084036.1, SSR3, TIPARP-AS1, TIPARP, METTL15P1, LINC00886.
- chr3:180,868,141–180,989,774, 3 genes, copy number 10: FXR1, AC108734.1, DNAJC19.
- chr4:21,304,468–21,523,709, 3 genes, copy number 22: AC110296.1, MIR7978, AC096576.7.
- chr5:165,782,805–167,168,401, 8 genes, copy number 9: AC008562.1, AC008489.1, RPL7P20, AC114321.1, AC026403.1, LINC01947, AC091819.2, AC091819.1.
- chr5:176,707,356–181,342,213, 184 genes, copy number 18–24 (broad region; genes not listed).
- chr8:150,584–1,801,711, 34 genes, copy number 9–15: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1, AF067845.2, AF067845.1, AF067845.5, AF067845.4, DLGAP2-AS1, AC100810.6, AC100810.2, CLN8, AC100810.3, AC100810.1.
- chr8:1,801,125–1,817,307, 3 genes, copy number 15: MIR3674, AC100810.7, MIR596.
- chr9:75,060,573–75,402,992, 5 genes, copy number 24 (within-gene range 4–24): NMRK1, OSTF1, Y_RNA, RNU6-1228P, AL158073.1.
- chr12:4,428,155–5,406,651, 29 genes, copy number 20: FGF6, C12orf4, RAD51AP1, DYRK4, AC005832.2, AC005832.4, AKAP3, AC005832.3, AC005832.1, NDUFA9, AC005833.1, GAU1, GALNT8, AC005833.2, KCNA6, AC006063.1, AC006063.3, AC006063.4, AC005906.2, KCNA1, AC006063.2, AC005906.1, KCNA5, AC005906.3, LINC02443, AC006206.2, AC006206.1, AC007848.2, AC007848.1.
- chr12:5,531,869–5,946,232, 1 gene, copy number 17 (within-gene range 3–17): ANO2.
- chr12:5,948,877–6,124,770, 1 gene, copy number 17 (within-gene range 3–17): VWF.
- chr12:10,358,464–10,410,146, 5 genes, copy number 17: LINC02598, KLRK1-AS1, KLRK1, KLRC4-KLRK1, KLRC4.
- chr12:10,412,315–10,420,595, 1 gene, copy number 17 (within-gene range 4–17): KLRC3.
- chr12:51,888,009–52,015,889, 6 genes, copy number 16: ANKRD33, AC025259.2, ACVRL1, ACVR1B, RNU6-574P, TAMALIN.
- chr12:54,230,942–56,163,496, 109 genes, copy number 13–38 (within-gene range 3–38) (broad region; genes not listed).
- chr12:56,237,807–56,334,053, 9 genes, copy number 21–32 (within-gene range 4–32): ANKRD52, COQ10A, AC073896.5, CS, AC073896.1, AC073896.2, AC073896.3, CNPY2, PAN2.
- chr12:57,234,903–57,452,062, 7 genes, copy number 19–21: NDUFA4L2, STAC3, AC137834.1, R3HDM2, RNU6-879P, AC126614.1, INHBC.
- chr12:57,529,633–57,984,761, 37 genes, copy number 9–44 (within-gene range 3–44): DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2.
- chr12:58,394,596–58,920,504, 4 genes, copy number 13–23: AC025578.1, AC020637.1, LINC02388, LRIG3.
- chr12:59,129,511–59,130,875, 1 gene, copy number 15: AC046129.1.
- chr12:59,523,278–59,586,943, 2 genes, copy number 28: LINC02448, RNU4-20P.
- chr12:61,668,302–62,279,150, 5 genes, copy number 27 (within-gene range 3–27): AC090629.1, TAFA2, RPL21P104, KRT8P19, RPS3P6.
- chr12:64,032,412–64,147,857, 5 genes, copy number 27: AC020611.1, AC020611.2, AC025576.3, AC025576.2, AC025576.1.
- chr12:65,824,460–66,037,714, 7 genes, copy number 27: HMGA2, AC107308.1, HMGA2-AS1, AC090673.1, MIR6074, LINC02425, RPL21P18.
- chr12:67,424,272–70,443,923, 73 genes, copy number 33 (broad region; genes not listed).
- chr12:76,351,797–76,660,884, 6 genes, copy number 19–22 (within-gene range 3–22): OSBPL8, AC107032.2, AC107032.3, RPL7AP9, YWHAQP7, AC107032.1.
- chr12:76,763,588–77,317,234, 7 genes, copy number 10 (within-gene range 3–10): ZDHHC17, CSRP2, AC124784.1, AC025161.1, E2F7, AC079030.1, LINC02464.
- chr12:125,983,702–126,191,406, 6 genes, copy number 11–14: LINC02826, LINC02359, AC005858.2, AC005858.3, AC005858.1, AC005888.1.
- chr12:126,915,199–127,284,328, 7 genes, copy number 23 (within-gene range 3–23): LINC02405, AC079949.3, AC079949.1, AC079949.5, AC079949.2, AC079949.6, LINC02376.
- chr15:22,664,359–23,121,324, 13 genes, copy number 20: WHAMMP3, AC138649.2, AC138649.5, AC138649.4, PDCD6IPP1, AC138649.3, AC138649.1, AC011767.1, NIPA1, NIPA2, CYFIP1, TUBGCP5, ELMO2P1.
- chr15:30,938,941–31,454,139, 10 genes, copy number 24 (within-gene range 5–24): MTMR10, RNU6-466P, AC009562.1, TRPM1, MIR211, LINC02352, AC012236.1, KLF13, UBE2CP4, AC104759.1.

Autosomal genes at a single copy (total copy number 1): 256. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
